Surgical pathology report (de-identified scan), TCGA case TCGA-77-7335, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7335-01A (Primary Tumor).

[page 1 of 3]
Anatomical Pathology

Final

Labno:

(HIST) Spec:

Anatomical Pathology

LUNG

Clinical Details:

NSCL Ca (left hilar).

Four specimens received:

A: LEFT LUNG

Macroscopy:

The specimen is labelled "left lung" and consists of a lung measuring 195 x 110 x 75 mm. There is a polypoid tumour protruding into the lumen of the main bronchus but not obviously involving the resection margin. Some of the bronchi appear dilated and are filled with mucus. Present just below the hilum and surrounding bronchi and blood vessels is the mass. It is growing into the bronchus as a polypoid mass. It involves the adjacent lymph node. It measures approximately 32 mm in maximal dimension. It has a firm pale appearance. Some adhesions are identified around the base of the lung. [Sections taken: bronchial resection margin-A1; vascular resection margin-A2; peribronchial lymph nodes A3-A4; tumour A5-A7; adjacent lung-A8].

B: HILAR LYMPH MODE

Macroscopy:

[page 2 of 3]
The specimen is labelled "hilar lymph node" and consists of a node with surrounding fibro-fatty tissue measuring 9 x 6 x 4 mm. [Bisected and blocked in toto, B1].

C: NO. 5 NODE

Macroscopy:

The specimen is labelled "No. 5 node" and consists of a lymph node measuring 18 x 15 x 8 mm. [Blocked in toto, 2 T.S.-C1].

D: NO. 7 NODE

Macroscopy:

The specimen is labelled "No. 7 node" and consists of a lymph node measuring 20 x 10 x 4 mm. [Bisected and blocked in toto, D1].

Microscopy - Specimens A-D:

Sections of the tumour show moderately differentiated keratinising squamous cell carcinoma involving left main bronchus and infiltrating around adjacent pulmonary vessels and into the pulmonary parenchyma. The tumour extends medially through pleura into adherent fibrofatty soft tissue containing nerve fibres. No perineural invasion is seen, but the tumour extends up to the surgical resection margin at this point and residual microscopic disease cannot be excluded. One of five peribronchial lymph nodes contains metastatic carcinoma. The bronchial resection margin is clear of tumour.

Sections of adjacent non-tumour lung show an area of scarring in relation to arteries showing evidence of recanalisation, interpreted as likely to be consequent to vascular changes related to tumour at

[page 3 of 3]
the lung hilum.

The hilar lymph node and lymph node designated number 5 show no evidence of malignancy. Metastatic squamous carcinoma is present in the separately submitted lymph node referenced as number 7.

Diagnosis:

Left lung: Moderately differentiated keratinising squamous carcinoma with extra-pleural soft tissue extension, metastatic to peribronchial and number 7 lymph nodes.

cc: [REDACTED]

Pathologist: DR [REDACTED] Registrar: DR [REDACTED]

Validated by DR [REDACTED]

Further sections of pericardium, mediastinal soft tissue and pleura have been submitted for histology (EB1-3). Tumour is present on the surface of mediastinal pleura and mediastinal soft tissue adjacent to the resected portion of pericardium, associated with strands of cardiac muscle at this site.

Therefore, as stated in the original report, the possibility of residual microscopic tumour in the mediastinum is not excluded on histologic grounds.

Addendum reported by DR [REDACTED]

Source: NCI Genomic Data Commons file 0c9cb559-460d-41e4-ac87-19d1a3f288a1 (TCGA-77-7335.B444C367-59C9-4E4E-9D58-829539C40296.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).